Gene-level copy-number profile of tumor specimen TCGA-24-1430-01A from TCGA case TCGA-24-1430, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 68.3 years (24,939 days).
Specimen TCGA-24-1430-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.51b1e818-3048-4c41-9074-e36212c7dd7e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-1430-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f6cb6ac4-040c-4273-97a6-1fdde3d29aa5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 19,900; copy number 2: 33,384; copy number 3: 5,659; copy number 4: 875.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-24-1430-01A-01D-0472-01): tumor purity 0.97, ploidy 1.86, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 17,479. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
